TCGA case TCGA-3X-AAV9 — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/41b97b11-acaa-4fbc-b3b0-0abc1bcac13b

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 72 years; Vital status: Dead; Days to death: 339 days.

Diagnoses (4)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 72.1 years (26,349 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: B; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 253 days; Days to treatment end: 326 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.
2. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; Tissue or organ of origin: Rectosigmoid junction; Classification of tumor: Prior primary; Age at diagnosis: 71.5 years (26,108 days); Days to diagnosis: -241 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -138 days; Treatment anatomic sites: Colon.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Lung, NOS. Age at diagnosis: 72.7 years (26,565 days); Days to diagnosis: 216 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
4. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Liver. Age at diagnosis: 72.7 years (26,565 days); Days to diagnosis: 216 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 216 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 216 days.
- Day 216 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 216 days.
- Days to follow up: 339 days; Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 538 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 35.
- Total Bilirubin 0.2 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.4].
- Creatinine 1.1 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.4].
- Albumin 2.7 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.3; Blood test normal range upper: 4.8].
- Platelets 254 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 52 kg; Height: 169 cm; BMI: 18.2.
- Timepoint category: Prior to Diagnosis; Risk factors: Ulcerative Colitis.

Family history
- Relative with cancer history: yes; Relationship type: Brother.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Kidney Cancer.
- Relatives with cancer history count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3X-AAV9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 740 mg.
  Slide TCGA-3X-AAV9-01A-07-TS7: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 9; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-3X-AAV9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3X-AAV9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Surgical procedure other: Right Hepatectomy.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy.
- Other malignancy form, Surgery: Other malignancy surgery type: Total Colectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 339 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 339 days; disease-free interval: event (new tumor event after initially disease-free), 216 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 216 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3X-AAV9-01A-72D-A416-01): tumor purity 0.24, ploidy 1.74, whole-genome doublings 0.
